Gene-level copy-number profile of tumor specimen ALCH-AEJZ-TTP1-A from ALCHEMIST case ALCH-AEJZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 74.3 years (27,152 days).
Specimen ALCH-AEJZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 63178e02-0bf9-4afd-a9f8-fc3f7e1cc745.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEJZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/5aaa88a2-23f9-49ef-8d5b-f6b796075699

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 457; copy number 1: 38,786; copy number 2: 18,284; copy number 3: 866; copy number 4: 327; copy number 5: 29; copy number 6: 1; copy number 8: 51; copy number 9: 1; copy number 10: 19; copy number 11: 9; copy number 13: 26; copy number 14: 12; copy number 15: 2; copy number 22: 6; copy number 28: 6; copy number 66: 5; copy number 71: 4; copy number 81: 13.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,870,483–28,881,835, 2 genes (within-gene range 0–1): AL009181.1, Y_RNA.
- chr2:218,264,129–218,453,295, 14 genes (within-gene range 0–1): AAMP, PNKD, TMBIM1, MIR6513, CATIP-AS2, MIR6810, RPL19P5, CATIP, CATIP-AS1, SLC11A1, CTDSP1, AC021016.2, MIR26B, VIL1.
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–1): NRBF2P6, ECEL1P3.
- chr3:138,777,832–138,889,957, 4 genes (within-gene range 0–2): GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3.
- chr5:178,130,996–178,166,562, 3 genes: RMND5B, NHP2, AC136632.2.
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr7:73,768,997–73,770,270, 1 gene: CLDN3.
- chr7:76,470,162–76,478,856, 2 genes (within-gene range 0–2): FDPSP2, AC005522.1.
- chr8:43,672,823–46,028,892, 3 genes: AC139365.2, AC139365.1, AC118650.1.
- chr11:68,312,591–68,449,275, 1 gene: LRP5.
- chr11:76,137,315–76,216,025, 4 genes (within-gene range 0–1): AP002340.1, WNT11, AP000785.1, LINC02761.
- chr11:134,008,215–134,067,936, 3 genes: LINC02730, LINC02731, AP000911.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 1,370 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,001,953–156,594,299, 30 genes, copy number 3 (within-gene range 1–3): AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1, MEF2D, Y_RNA, AL365181.1, IQGAP3, TTC24, NAXE.
- chr1:213,051,233–214,664,571, 17 genes, copy number 3: RPS6KC1, RPL31P13, AL592402.1, AC096639.1, PROX1-AS1, LINC00538, PROX1, AC011700.1, AL606537.1, SMYD2, AL929236.1, PTPN14, AL445305.1, KRT18P12, CENPF, ABHD17AP3, UBE2V1P13.
- chr2:60,823,069–60,931,612, 4 genes, copy number 71 (within-gene range 2–71): LINC01185, RN7SL632P, RPL21P33, REL.
- chr2:62,168,862–62,350,739, 5 genes, copy number 66: AC018462.2, B3GNT2, MIR5192, RN7SL51P, AC093159.2.
- chr2:150,169,474–150,356,460, 2 genes, copy number 3: LINC01818, LINC01817.
- chr2:172,137,345–178,402,893, 136 genes, copy number 3–4 (broad region; genes not listed).
- chr3:148,695,994–151,437,072, 76 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr3:156,037,701–156,539,138, 1 gene, copy number 3 (within-gene range 2–3): KCNAB1.
- chr3:156,143,570–189,897,276, 524 genes, copy number 3–22 (broad region; genes not listed).
- chr4:89,879,532–89,954,629, 1 gene, copy number 3: MMRN1.
- chr4:94,117,792–96,818,864, 19 genes, copy number 3: AC096746.1, HMGB3P15, SMARCAD1, HPGDS, AC109925.1, RPL35AP11, PDLIM5, AC108067.1, BMPR1B-DT, BMPR1B, UNC5C, AC106881.1, RPL30P6, PDHA2, RNU6-1059P, RNU6-34P, AC096661.1, LINC02267, RN7SKP28.
- chr4:98,251,688–98,443,858, 3 genes, copy number 3: AC019077.1, RAP1GDS1, AC058823.1.
- chr4:178,685,886–190,092,279, 180 genes, copy number 3 (broad region; genes not listed).
- chr5:58,198–1,816,048, 64 genes, copy number 3 (broad region; genes not listed).
- chr6:10,365,593–10,709,782, 19 genes, copy number 10: AL138885.1, TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1.
- chr6:10,886,831–11,044,305, 3 genes, copy number 8 (within-gene range 2–8): SYCP2L, ELOVL2, AL121955.1.
- chr6:43,171,269–45,377,953, 66 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr8:126,474,189–127,742,951, 19 genes, copy number 28–81: AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr10:3,232,264–3,267,216, 2 genes, copy number 4 (within-gene range 4–5): LINC02668, AL139280.1.
- chr10:4,786,629–5,135,226, 10 genes, copy number 4: AKR1E2, AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P.
- chr11:68,612,899–71,252,577, 64 genes, copy number 8–13 (within-gene range 2–13) (broad region; genes not listed).
- chr13:72,727,749–73,661,891, 14 genes, copy number 4: BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr14:18,395,626–18,412,264, 1 gene, copy number 6: CR383658.2.
- chr16:46,469,341–46,569,097, 1 gene, copy number 3 (within-gene range 1–3): ANKRD26P1.
- chr20:40,696,499–43,189,970, 28 genes, copy number 3 (within-gene range 2–3): AL035665.1, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3, PTPRT, AL035666.1, AL031656.1, PTPRT-AS1.
- chr20:62,774,121–63,843,915, 62 genes, copy number 3 (broad region; genes not listed).
- chr21:10,413,477–13,016,692, 8 genes, copy number 3: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.
- chr22:18,400,407–18,577,968, 8 genes, copy number 3–13: PPP1R26P3, FAM230A, AC023490.2, FAM247B, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1.
- chr22:18,636,445–18,719,341, 3 genes, copy number 9–15: CA15P2, PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 36,496. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
